Somatic mutation profile of tumor specimen TCGA-ZG-A9NI-01A (aliquot TCGA-ZG-A9NI-01A-11D-A41K-08) from TCGA case TCGA-ZG-A9NI, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 73.1 years (26,697 days).
Specimen TCGA-ZG-A9NI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb739da6-1972-4ff7-b7fa-f7303ba43438.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9NI-10A (Blood Derived Normal), aliquot TCGA-ZG-A9NI-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3a1b630-1791-4098-a73d-21451bf4e1f5

The open-access MAF lists 90 somatic variants for this specimen: 78 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 64, Silent 12, Nonsense Mutation 5, Splice Site 4, Splice Region 2, Frame Shift Ins 1, Frame Shift Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AATK | c.4110G>C p.E1370D (on ENST00000326724 / NM_001080395.3; = p.E1267D on NM_004920.2) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs759410819, COSV100353256; called by muse, varscan2
- AC013489.1 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs772893746, COSV99183897; called by muse, varscan2
- AKT3 | c.302C>G p.A101G | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV99796697; called by muse, mutect2, varscan2
- ARHGAP9 | c.2108G>A p.R703H (on ENST00000393797 / NM_001319850.2; = p.R684H on NM_032496.4) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs760663898, COSV99954683; called by muse, mutect2, varscan2
- ATF6 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764722601, COSV63406075; called by muse, mutect2
- CCT8 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV99726158; called by muse, varscan2
- CEP120 | c.2083G>C p.E695Q | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs1389891396, COSV100071464, COSV60266935, COSV60269460; called by muse, mutect2, varscan2
- CERT1 | c.1573G>C p.V525L (on ENST00000405807 / NM_001130105.1; = p.V397L on NM_005713.3) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.07); catalogued as COSV99783737; called by muse, mutect2, varscan2
- CNBD1 | c.8T>C p.M3T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs113899610; called by muse, mutect2, varscan2
- CRIM1 | c.938C>G p.S313C | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99754460; called by muse, mutect2, varscan2
- CTTNBP2 | c.501C>A p.N167K | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99354850; called by muse, mutect2, varscan2
- CXorf56 | c.344C>T p.T115M (on ENST00000536133 / NM_001170570.2; = p.T129M on NM_022101.4) | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.117); catalogued as rs753049409, COSV100233460; called by muse, mutect2, varscan2
- CXorf58 | c.879G>C p.M293I | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV101003098; called by muse, mutect2, varscan2
- EFCC1 | c.1471G>C p.E491Q | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.571); catalogued as COSV101460027; called by muse, mutect2, varscan2
- ERI2 | c.119T>C p.I40T | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs777042188, COSV54474034, COSV99759474; called by muse, mutect2, varscan2
- FAT4 | c.8770G>T p.A2924S | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.995); catalogued as COSV100630164, COSV58681744; called by muse, mutect2, varscan2
- FBXO21 | c.1283T>G p.L428R | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100401865; called by muse, mutect2, varscan2
- GAD2 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.362); catalogued as rs768604380, COSV99394035; called by muse, mutect2
- GCFC2 | c.1166G>C p.S389T | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100319727; called by muse, mutect2, varscan2
- GLB1L3 | c.429G>C p.L143= | Splice Region (SNP) | VAF 18/162 reads (11%) | catalogued as COSV101111120; called by mutect2, varscan2
- GLYCTK | c.1396A>T p.T466S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99980938; called by muse, mutect2, varscan2
- GNAI2 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs782279425, COSV56494032, COSV99806949; called by muse, mutect2, varscan2
- HECTD4 | c.12020C>A p.T4007N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV101108372; called by muse, mutect2, varscan2
- HOXD8 | c.574C>A p.Q192K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as rs1442503344, COSV57484998; called by muse, mutect2, varscan2
- IGDCC4 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100733145; called by muse, mutect2, varscan2
- ITPRIP | c.779C>A p.T260N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV99532725; called by muse, mutect2
- ITSN2 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 19/60 reads (32%) | catalogued as COSV100744167; called by muse, mutect2, varscan2
- KCNE3 | c.182T>A p.I61N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100035696; called by muse, mutect2
- KCNT2 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763311319, COSV99656702; called by muse, mutect2, varscan2
- KDM5A | c.3616A>T p.K1206* | Nonsense Mutation (SNP) | VAF 31/107 reads (29%) | catalogued as COSV101239057; called by muse, mutect2, varscan2
- KIF1C | c.3251C>T p.P1084L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100297300; called by muse, mutect2, varscan2
- KIRREL2 | c.182T>A p.L61Q | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99384436; called by muse, mutect2, varscan2
- LPIN1 | c.2152A>T p.K718* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99878184; called by muse, mutect2
- LRP1B | c.7685G>A p.R2562H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs774407084, COSV67223392; called by muse, mutect2, varscan2
- LRRC55 | c.508A>G p.S170G | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as rs1233065133, COSV101546786; called by muse, mutect2, varscan2
- LRRC8B | c.596T>C p.I199T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs770605628, COSV100446693; called by muse, mutect2, varscan2
- MACF1 | c.10949C>G p.S3650C (on ENST00000372915; = p.S1583C on NM_012090.5) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as COSV99246828; called by muse, mutect2, varscan2
- MAOB | c.749T>G p.L250R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.161); catalogued as COSV100956242; called by muse, mutect2, varscan2
- MCM3AP | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52440759; called by muse, mutect2, varscan2
- MFSD13A | c.92A>C p.N31T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99488042; called by muse, mutect2, varscan2
- MMUT | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1314161465, COSV51272523, COSV99222575; called by muse, mutect2, varscan2
- MMUT | c.433G>T p.G145C | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1237080100, CM060381, COSV99222577; called by muse, mutect2, varscan2
- MUC5B | c.13405G>A p.A4469T | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs1418260346, COSV71589675; called by muse, mutect2, varscan2
- MXRA5 | c.3013C>A p.P1005T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV54225663, COSV99479209; called by muse, mutect2, varscan2
- MYH6 | c.2098G>A p.V700M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs767142932, CM107533, COSV100676802; called by muse, mutect2, varscan2
- NEU2 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.28); catalogued as rs144556397; called by muse, mutect2, varscan2
- NFAM1 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100216080; called by muse, mutect2
- NQO1 | c.553T>A p.L185I | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1210871937, COSV100276705; called by muse, mutect2, varscan2
- NR3C2 | c.1832C>T p.S611L | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100679753; called by muse, mutect2, varscan2
- NRXN3 | c.1615G>T p.D539Y (on ENST00000335750 / NM_001330195.2; = p.D166Y on NM_004796.6) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100209019; called by muse, mutect2, varscan2
- OLFML2B | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99668915; called by muse, mutect2
- OR11H6 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.17); catalogued as COSV100209970, COSV59643945; called by muse, mutect2
- OR51A4 | c.670A>G p.K224E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100985366; called by muse, mutect2, varscan2
- PCLO | c.12068G>A p.S4023N | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV100437721; called by muse, mutect2, varscan2
- PDZRN4 | c.1058C>A p.T353N (on ENST00000402685 / NM_001164595.2; = p.T95N on NM_013377.4) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1194240391, COSV100115451; called by muse, mutect2, varscan2
- PKHD1L1 | c.1903G>T p.E635* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as COSV101006825; called by muse, mutect2, varscan2
- PLA2G7 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99221605; called by muse, mutect2, varscan2
- PLCE1 | c.1956G>A p.R652= | Splice Region (SNP) | VAF 4/24 reads (17%) | catalogued as COSV53358450, COSV99597143; called by muse, mutect2
- QSER1 | c.5137G>A p.V1713I (on ENST00000399302; = p.V1842I on NM_001076786.3) | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs906103849, COSV101234965; called by muse, mutect2
- RALGAPA2 | c.3368C>A p.S1123* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as rs1413377716, COSV99175010; called by muse, mutect2, varscan2
- RGS6 | c.1418G>C p.*473Sext*36 | Nonstop Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100666997; called by muse, mutect2, varscan2
- RNF139 | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as COSV99413716; called by muse, mutect2, varscan2
- SEC24C | c.2672C>G p.S891C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100227155; called by muse, mutect2, varscan2
- SERTAD4 | c.370G>C p.V124L | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV100882666; called by muse, mutect2, varscan2
- SLC5A8 | c.574C>G p.Q192E | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101610607, COSV73310684; called by muse, mutect2
- SLC8A3 | c.853A>T p.I285F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV100776376; called by muse, mutect2, varscan2
- SP140 | c.858G>C p.E286D | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.145); catalogued as COSV100614075; called by muse, mutect2
- SPEM1 | c.695C>A p.A232E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100080955, COSV100081271; called by muse, mutect2, varscan2
- SULF2 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as rs116302994; called by muse, mutect2, varscan2
- TBX20 | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV101282425; called by muse, mutect2
- TLR2 | c.1806C>G p.I602M | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV99472544; called by muse, mutect2
- ZSCAN4 | c.1226C>G p.S409C | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99990344; called by muse, mutect2, varscan2
- IL9 | c.115-2del p.X39_splice | Splice Site (DEL) | VAF 11/114 reads (10%) | called by mutect2, pindel, varscan2
- MX2 | c.1414+3_1414+6del p.X472_splice | Splice Site (DEL) | VAF 14/88 reads (16%) | called by mutect2, pindel, varscan2
- QSOX2 | c.582_584+2del p.X194_splice | Splice Site (DEL) | VAF 30/80 reads (38%) | called by mutect2, pindel, varscan2
- RARS2 | c.616del p.Y206Mfs*14 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- SETD2 | c.7143dup p.S2382Lfs*47 | Frame Shift Ins (INS) | VAF 13/66 reads (20%) | called by mutect2, pindel, varscan2
- TP53BP2 | c.2863-4_2868del p.X955_splice (on ENST00000343537 / NM_001031685.3; = p.X826_splice on NM_005426.2) | Splice Site (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- ATG14 | c.657A>T p.A219= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs1453153651, COSV99903026; called by muse, mutect2, varscan2
- AXL | c.1309C>T p.L437= | Silent (SNP) | VAF 18/149 reads (12%) | catalogued as COSV99997251; called by muse, mutect2, varscan2
- CCT8 | c.369G>C p.L123= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs1433618068, COSV99726157; called by muse, varscan2
- CDH8 | c.1722A>G p.L574= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100184128; called by muse, mutect2, varscan2
- CLTC | c.2784G>T p.L928= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV99292882; called by muse, mutect2, varscan2
- FANCM | c.3435C>T p.D1145= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as rs760913813, COSV57499227; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAT3 | c.11433C>A p.V3811= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV99970946; called by muse, mutect2, varscan2
- H2AX | c.102G>A p.L34= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99598189; called by muse, mutect2, varscan2
- KIF21A | c.711C>T p.T237= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs749963979, COSV100735656; called by muse, mutect2, varscan2
- NFATC1 | c.507G>A p.S169= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs146706357; called by muse, mutect2, varscan2
- PCLO | c.2637T>C p.P879= | Silent (SNP) | VAF 28/266 reads (11%) | catalogued as COSV100437722; called by muse, mutect2
- TBCE | c.501C>T p.G167= (on ENST00000366601; = p.G230= on NM_003193.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as COSV100783252; called by muse, mutect2
